Somatic mutation profile of tumor specimen TCGA-EB-A6QY-01A (aliquot TCGA-EB-A6QY-01A-12D-A32N-08) from TCGA case TCGA-EB-A6QY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 71.8 years (26,216 days).
Specimen TCGA-EB-A6QY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d579634-137f-4f7e-b889-2cd3e035ef7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EB-A6QY-10B (Blood Derived Normal), aliquot TCGA-EB-A6QY-10B-01D-A32N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/15784a44-ef5b-420c-a436-9b6839fbec7b

The open-access MAF lists 739 somatic variants for this specimen: 486 protein-altering or splice-affecting, 238 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 450, Silent 238, Nonsense Mutation 13, Splice Site 13, Intron 6, RNA 6, Frame Shift Del 4, Translation Start Site 3, Splice Region 3, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 60/160 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- BRAF | c.1918G>A p.V640M (on ENST00000288602 / NM_001374244.1; = p.V600M on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as rs121913378, COSV56066607, COSV56075762, COSV56124012, COSV56152883; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- GBA | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs80356771, CM110322, CM900108; ClinVar: pathogenic / risk factor; called by mutect2, varscan2
- ABCA12 | c.7321T>C p.S2441P (on ENST00000272895 / NM_173076.3; = p.S2123P on NM_015657.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99789348; called by muse, mutect2, varscan2
- ABCA2 | c.1355+2T>C p.X452_splice (on ENST00000614293; = p.X422_splice on NM_001606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99687378; called by muse, mutect2, varscan2
- ABCA8 | c.4483C>T p.L1495F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV52195400; called by muse, mutect2, varscan2
- ABCC1 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 51/406 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs775155522, COSV60680588; called by muse, mutect2, varscan2
- ABCC12 | c.3720G>A p.M1240I | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60916265; called by muse, mutect2, varscan2
- ACD | c.851C>T p.P284L (on ENST00000620338; = p.P195L on NM_022914.3) | Missense Mutation (SNP) | VAF 65/199 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV99537579; called by muse, mutect2, varscan2
- ACTRT2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs189197365; called by muse, mutect2, varscan2
- ADAMTS19 | c.3391G>A p.E1131K | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.709); catalogued as rs553809104, COSV50749496; called by muse, mutect2, varscan2
- ADAMTS2 | c.3365C>T p.T1122I | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1211342851, COSV99281653; called by muse, mutect2, varscan2
- ADAMTSL1 | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs757020927, COSV52813836; called by muse, mutect2, varscan2
- ADCK5 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV100450336; called by muse, mutect2, varscan2
- ADGRE1 | c.1459G>A p.E487K | Missense Mutation (SNP) | VAF 27/133 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs143078439; called by muse, mutect2, varscan2
- ADGRF2 | c.985G>A p.E329K (on ENST00000296862 / NM_001368115.2; = p.E261K on NM_153839.7) | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.786); catalogued as rs764110566, COSV57286334; called by muse, mutect2, varscan2
- ADGRF2 | c.2014G>A p.D672N (on ENST00000296862 / NM_001368115.2; = p.D604N on NM_153839.7) | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.04); catalogued as rs144129468, COSV57286912; called by muse, mutect2, varscan2
- ADH1A | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1039874400, COSV52924296; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 107/441 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2, varscan2
- AHCTF1 | c.6748C>T p.P2250S (on ENST00000366508; = p.P2224S on NM_015446.5) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780896259, COSV100403460; called by muse, mutect2, varscan2
- AHRR | c.1703C>T p.T568I | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as rs1242038262, COSV100326975; called by muse, mutect2, varscan2
- ALX1 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as rs150997122, COSV57492012; called by muse, mutect2, varscan2
- AMPD3 | c.1190G>A p.G397E (on ENST00000396553 / NM_001025389.2; = p.G406E on NM_000480.3) | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101158135; called by muse, mutect2, varscan2
- ANKRD30A | c.1777A>C p.K593Q (on ENST00000611781; = p.K537Q on NM_052997.2) | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.099); catalogued as COSV100653254; called by muse, mutect2, varscan2
- ANO2 | c.1391A>T p.Y464F (on ENST00000356134 / NM_001278597.3; = p.Y468F on NM_001278596.3) | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.482); catalogued as COSV100500426; called by muse, mutect2
- ANO4 | c.628C>T p.R210W (on ENST00000392977 / NM_001286615.2; = p.R175W on NM_178826.4) | Missense Mutation (SNP) | VAF 173/609 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.719); catalogued as rs372521580; called by muse, mutect2, varscan2
- ANPEP | c.1072G>A p.G358R | Missense Mutation (SNP) | VAF 34/120 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100262874; called by muse, mutect2, varscan2
- APOB | c.13292A>G p.N4431S | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99264858; called by muse, mutect2, varscan2
- APOB | c.11959C>T p.H3987Y | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV99264860; called by muse, mutect2, varscan2
- APOB | c.4277T>A p.L1426Q | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99264862; called by muse, mutect2, varscan2
- APOBEC3F | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 92/311 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.062); catalogued as COSV100415161; called by muse, mutect2
- ARID1A | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 21/174 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV100251077, COSV104411591; called by muse, mutect2, varscan2
- ARID2 | c.1913-1G>A p.X638_splice | Splice Site (SNP) | VAF 25/102 reads (25%) | catalogued as COSV57610763; called by muse, mutect2, varscan2
- ARMC9 | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs563490038, COSV63022089; called by muse, mutect2, varscan2
- ASTN2 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.941); catalogued as COSV100526224; called by muse, mutect2, varscan2
- ASXL3 | c.353G>A p.G118E | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); catalogued as COSV52473865, COSV52479896; called by muse, mutect2, varscan2
- ATP6V0E2 | c.240G>A p.W80* (on ENST00000425642; = p.W129* on NM_145230.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 33/169 reads (20%) | catalogued as COSV101374578; called by muse, mutect2, varscan2
- ATP6V0E2 | c.241G>A p.E81K (on ENST00000425642; = p.E130K on NM_145230.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/167 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV101374579; called by muse, mutect2, varscan2
- ATP9A | c.2662C>T p.P888S | Missense Mutation (SNP) | VAF 88/199 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100124699; called by muse, mutect2, varscan2
- ATRNL1 | c.2989C>T p.L997F | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100370091; called by muse, mutect2, varscan2
- ATXN7L2 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 65/230 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV63992950; called by muse, mutect2, varscan2
- BAAT | c.506G>A p.G169D | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.015); catalogued as rs1182137359, COSV99408440; called by muse, mutect2, varscan2
- BBOX1 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as rs777657760, COSV99589577; called by muse, mutect2, varscan2
- BBS9 | c.2650G>A p.G884R (on ENST00000242067 / NM_001348036.1; = p.G844R on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/187 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.989); catalogued as COSV54158509; called by muse, mutect2, varscan2
- BCL2L11 | c.574C>T p.R192C (on ENST00000393256 / NM_138621.5; = p.R132C on NM_006538.5) | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs758817904, COSV58027602; called by muse, mutect2, varscan2
- BCL9L | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs530938290, COSV100599718; called by muse, mutect2, varscan2
- BEND3 | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.749); catalogued as rs782720317; called by muse, mutect2
- BEST3 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866576996, COSV100437703; called by muse, mutect2, varscan2
- BICDL2 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs371864506; called by muse, mutect2, varscan2
- BLVRA | c.35T>C p.V12A | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.994); catalogued as COSV55515719, COSV55516590; called by muse, mutect2, varscan2
- BPI | c.122C>T p.S41F (on ENST00000262865; = p.S37F on NM_001725.3) | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99480528; called by muse, mutect2, varscan2
- BRD1 | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53462000; called by muse, mutect2
- BRINP1 | c.2248C>T p.L750F | Missense Mutation (SNP) | VAF 105/253 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as COSV56296869; called by muse, mutect2, varscan2
- C2orf78 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as COSV101280943; called by muse, mutect2, varscan2
- C6 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV54704604; called by muse, mutect2
- CA6 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 142/428 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV66262876; called by muse, mutect2, varscan2
- CACNA1C | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1310223974, COSV59791416; called by muse, mutect2, varscan2
- CACNA1G | c.6971C>T p.P2324L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs866616905, COSV61739349; called by muse, mutect2, varscan2
- CACNA2D1 | c.1766G>A p.R589K (on ENST00000356253 / NM_001366867.1; = p.R570K on NM_000722.4) | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.98); PolyPhen benign (0.015); catalogued as COSV100666392, COSV62391344; called by muse, mutect2
- CACNA2D4 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV99765429; called by muse, mutect2
- CACNB2 | c.1351G>A p.E451K (on ENST00000324631 / NM_201596.3; = p.E396K on NM_000724.4) | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99993882; called by muse, mutect2, varscan2
- CACNB4 | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV99137988; called by muse, mutect2, varscan2
- CAD | c.1930G>T p.E644* | Nonsense Mutation (SNP) | VAF 46/119 reads (39%) | catalogued as COSV99254815; called by muse, mutect2, varscan2
- CALCRL | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV101130916; called by muse, mutect2
- CASP3 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 68/165 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100394950; called by muse, mutect2, varscan2
- CASR | c.1438G>A p.G480R (on ENST00000490131; = p.G557R on NM_000388.4) | Missense Mutation (SNP) | VAF 73/274 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99948765; called by muse, mutect2, varscan2
- CASR | c.1439G>A p.G480E (on ENST00000490131; = p.G557E on NM_000388.4) | Missense Mutation (SNP) | VAF 74/275 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as CM014525, COSV99948767; called by muse, mutect2, varscan2
- CCDC153 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 51/98 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100501246, COSV100501302; called by muse, mutect2, varscan2
- CCDC181 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); catalogued as rs1415376377, COSV100890292; called by muse, mutect2, varscan2
- CCDC40 | c.1282G>A p.E428K | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99481603; called by muse, mutect2, varscan2
- CCNDBP1 | c.883A>T p.I295L | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.077); catalogued as COSV100281592; called by muse, mutect2, varscan2
- CD163 | c.1736G>A p.R579K | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.764); catalogued as COSV63136965; called by muse, mutect2, varscan2
- CD2 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.081); catalogued as COSV65645046; called by muse, mutect2, varscan2
- CD38 | c.671G>A p.S224N | Missense Mutation (SNP) | VAF 71/298 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.653); catalogued as COSV99882523; called by muse, mutect2, varscan2
- CDA | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV100906273, COSV100906334; called by muse, mutect2, varscan2
- CDH10 | c.2095C>T p.R699W | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV52574144; called by muse, mutect2, varscan2
- CDH2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1313840328, COSV52270856; called by muse, mutect2, varscan2
- CDH7 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59884653; called by muse, mutect2, varscan2
- CDKL2 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.193); catalogued as COSV56732526; called by muse, mutect2, varscan2
- CELA2B | c.778G>A p.D260N | Missense Mutation (SNP) | VAF 63/246 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs1308898782, COSV100423590, COSV61600879; called by muse, mutect2, varscan2
- CFHR4 | c.1307C>T p.S436F (on ENST00000367416 / NM_001201551.2; = p.S190F on NM_006684.5) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52235177, COSV99260064; called by muse, mutect2, varscan2
- CHCHD3 | c.547T>A p.C183S | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99365960; called by muse, mutect2, varscan2
- CHD1 | c.3023C>T p.P1008L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.134); catalogued as COSV99399315; called by muse, mutect2, varscan2
- CHD5 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV99313225; called by muse, mutect2
- CHD7 | c.3268G>A p.D1090N | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV101418155; called by muse, mutect2, varscan2
- CHRM2 | c.20C>T p.S7F | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV100281050; called by muse, mutect2, varscan2
- CLIP2 | c.1661A>C p.K554T | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.042); catalogued as COSV99791315; called by muse, mutect2, varscan2
- CLK1 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100362224; called by muse, mutect2, varscan2
- CLSTN3 | c.2156C>T p.P719L | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV56935364; called by muse, mutect2, varscan2
- CMYA5 | c.6898G>A p.E2300K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs764888673, COSV71409361; called by muse, mutect2, varscan2
- CNTN5 | c.1694C>T p.S565L | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.081); catalogued as rs368554933; called by muse, mutect2, varscan2
- COL11A1 | c.4505C>T p.P1502L | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.447); catalogued as COSV100615912; called by muse, mutect2, varscan2
- COL18A1 | c.2119G>A p.E707K (on ENST00000359759 / NM_130444.3; = p.E472K on NM_030582.4) | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.587); catalogued as COSV100700615, COSV62707290; called by muse, mutect2, varscan2
- COL19A1 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as COSV100505946, COSV59576167; called by muse, mutect2, varscan2
- COL4A2 | c.2857G>A p.G953R | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100847299; called by muse, mutect2
- COL4A3 | c.2896C>T p.P966S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.211); catalogued as COSV100516701; called by muse, mutect2, varscan2
- COL6A3 | c.6940G>A p.G2314R | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769640641, COSV55087998; called by muse, mutect2, varscan2
- COL6A3 | c.6809G>A p.G2270E | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867239815, COSV99797340; called by muse, mutect2
- COL9A1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.472); catalogued as COSV100294481; called by muse, mutect2, varscan2
- COL9A1 | c.2090G>A p.G697E | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100294484; called by muse, mutect2, varscan2
- CPED1 | c.2174-1G>A p.X725_splice | Splice Site (SNP) | VAF 45/199 reads (23%) | catalogued as COSV100120438; called by muse, mutect2, varscan2
- CPT1C | c.1158C>T p.P386= | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as COSV99773349; called by muse, mutect2, varscan2
- CRIM1 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 52/224 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV99753005; called by muse, mutect2, varscan2
- CRLF2 | c.545C>T p.S182F | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as COSV101053664; called by muse, mutect2, varscan2
- CRTAC1 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.808); catalogued as COSV100085325; called by muse, mutect2, varscan2
- CRYBB1 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.139); catalogued as rs1347175227, COSV99315928; called by muse, mutect2, varscan2
- CRYBB1 | c.433-1G>A p.X145_splice | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as COSV99315929; called by muse, mutect2, varscan2
- CRYBB2 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as CM162359, COSV101236725; called by muse, mutect2, varscan2
- CRYGD | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100006017; called by muse, varscan2
- CRYL1 | c.521C>T p.A174V | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV100004287; called by muse, mutect2, varscan2
- CSF1R | c.1406A>T p.Q469L | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV99641514; called by muse, mutect2, varscan2
- CSF2RA | c.310G>A p.G104R | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100817636; called by muse, mutect2, varscan2
- CTSG | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.024); catalogued as COSV53536981; called by muse, mutect2, varscan2
- CYFIP2 | c.1224G>A p.M408I | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0.284); catalogued as COSV100556287; called by muse, mutect2, varscan2
- CYP7B1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.01); catalogued as rs267601966, COSV59586726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAB1 | c.1329G>A p.M443I (on ENST00000371231; = p.M410I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs766791551, COSV64698451; called by muse, mutect2, varscan2
- DCAF11 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100386629; called by muse, mutect2, varscan2
- DCX | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as CM087669, COSV100576763, COSV57568905; called by muse, mutect2, varscan2
- DDX23 | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 79/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100339754; called by muse, mutect2, varscan2
- DDX41 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as COSV100286497; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DHX38 | c.3292C>T p.P1098S | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.806); catalogued as COSV99194172; called by muse, mutect2, varscan2
- DKK1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.755); catalogued as rs1265701638, COSV100906465, COSV100906524; called by muse, mutect2, varscan2
- DLC1 | c.1349-1G>A p.X450_splice (on ENST00000276297 / NM_001348081.2; = p.X13_splice on NM_006094.5) | Splice Site (SNP) | VAF 29/59 reads (49%) | catalogued as COSV99362352; called by muse, mutect2, varscan2
- DNAAF5 | c.1889C>T p.S630F | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1332223769, COSV99859581; called by muse, mutect2
- DNAH10 | c.4868G>A p.R1623K (on ENST00000409039; = p.R1562K on NM_207437.3) | Missense Mutation (SNP) | VAF 21/231 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV101292153, COSV68989564; called by muse, mutect2
- DNAH5 | c.11971C>T p.L3991F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99447913; called by muse, mutect2, varscan2
- DNAH5 | c.9286C>T p.R3096* | Nonsense Mutation (SNP) | VAF 26/138 reads (19%) | catalogued as rs868444911, CM147994, COSV54213734; called by muse, mutect2, varscan2
- DNAH5 | c.6487C>T p.R2163W | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757370062, COSV99447916; called by muse, mutect2, varscan2
- DOCK8 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101210206; called by muse, mutect2, varscan2
- DPPA3 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1565454912, COSV100559863, COSV61503283; called by muse, mutect2, varscan2
- DSC3 | c.307A>G p.K103E | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.014); catalogued as COSV100844570; called by muse, mutect2, varscan2
- DYNC1I1 | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as COSV61457338; called by muse, mutect2
- E2F6 | c.369T>A p.H123Q | Missense Mutation (SNP) | VAF 22/161 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.828); catalogued as COSV100215293; called by muse, varscan2
- ECE1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs565366984, COSV51668107; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs200277467, COSV100348980, COSV100349279; called by muse, mutect2, varscan2
- ENO3 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.488); catalogued as rs1364760081, COSV99236367; called by muse, mutect2, varscan2
- EPB41L2 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100440497; called by muse, mutect2, varscan2
- EPPK1 | c.3982C>T p.P1328S | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV101599797; called by muse, mutect2, varscan2
- EPS8 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs369986759; called by muse, mutect2, varscan2
- ERICH3 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV100443927; called by muse, mutect2, varscan2
- EXPH5 | c.1220G>A p.R407K | Missense Mutation (SNP) | VAF 80/242 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.098); catalogued as COSV99761342; called by muse, mutect2, varscan2
- FAM117B | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 41/243 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100287371; called by muse, mutect2, varscan2
- FAM118B | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 146/344 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100796862; called by muse, mutect2, varscan2
- FAM135B | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 77/277 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199787210; called by muse, mutect2, varscan2
- FAM209B | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs759935728, COSV64915053; called by muse, mutect2, varscan2
- FAM3B | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63613333; called by muse, mutect2, varscan2
- FAT4 | c.7963G>A p.E2655K | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT tolerated (0.92); PolyPhen probably damaging (0.993); catalogued as rs556536853, COSV58679417; called by muse, mutect2, varscan2
- FBN3 | c.6497-1G>A p.X2166_splice | Splice Site (SNP) | VAF 31/134 reads (23%) | catalogued as COSV99560539; called by muse, mutect2, varscan2
- FEZF1 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 105/279 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.357); catalogued as COSV100484468, COSV58658771; called by muse, mutect2, varscan2
- FLG | c.7652A>C p.Q2551P | Missense Mutation (SNP) | VAF 169/701 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV100911400; called by muse, mutect2, varscan2
- FLG | c.1886G>A p.G629E | Missense Mutation (SNP) | VAF 278/746 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV100911401; called by muse, mutect2, varscan2
- FMO3 | c.1138C>T p.P380S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as COSV100882421; called by muse, mutect2, varscan2
- FNDC1 | c.1936G>A p.D646N | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.421); catalogued as COSV99795435; called by muse, mutect2, varscan2
- FOXA2 | c.958G>A p.G320R (on ENST00000377115 / NM_153675.3; = p.G326R on NM_021784.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0.216); catalogued as rs1393096780, COSV101008305; called by muse, mutect2
- FOXJ3 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV100691648; called by muse, mutect2, varscan2
- FOXRED2 | c.1658C>T p.P553L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV99340810; called by muse, mutect2, varscan2
- FPR2 | c.20C>T p.T7I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100389225; called by muse, mutect2, varscan2
- FREM1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs1377595838, COSV101084176; called by muse, mutect2
- FRG2C | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 26/319 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.981); catalogued as rs1163631660; called by muse, mutect2
- FRMPD4 | c.3725C>T p.S1242F | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.309); catalogued as COSV66213807; called by muse, mutect2, varscan2
- GABPB2 | c.614C>T p.T205I | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV100927209; called by muse, mutect2
- GABRA5 | c.497G>C p.R166P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100164990, COSV100164994; called by muse, mutect2
- GABRB2 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.803); catalogued as COSV99195855; called by muse, mutect2, varscan2
- GALM | c.635G>A p.G212E | Missense Mutation (SNP) | VAF 43/144 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV99697119; called by muse, mutect2, varscan2
- GALNT6 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as rs749412571, COSV100695382; called by muse, mutect2, varscan2
- GALNT9 | c.1135G>A p.E379K (on ENST00000328957 / NM_001122636.2; = p.E13K on NM_021808.3) | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as rs751954230, COSV61095949; called by muse, mutect2, varscan2
- GARRE1 | c.197C>T p.A66V | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.059); catalogued as COSV100209251; called by muse, mutect2, varscan2
- GBA | c.1503C>A p.N501K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM972851, COSV100516293; called by muse, mutect2, varscan2
- GCKR | c.1123A>G p.K375E | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV99268943; called by muse, mutect2, varscan2
- GCSAML | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100825930, COSV63579630; called by muse, mutect2, varscan2
- GDF3 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 43/178 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867390778, COSV61712125; called by muse, mutect2, varscan2
- GEMIN6 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs141104490; called by muse, mutect2, varscan2
- GHR | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 43/156 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); catalogued as rs866523407, COSV100050368; called by muse, mutect2, varscan2
- GIGYF1 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as rs1328572144, COSV99309140; called by muse, mutect2, varscan2
- GIMAP1 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as COSV100212057, COSV100212070; called by muse, mutect2
- GIMAP4 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99750573; called by muse, mutect2, varscan2
- GLRB | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 55/113 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52415538; called by muse, mutect2, varscan2
- GLYAT | c.803G>A p.S268N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV99557243; called by muse, mutect2, varscan2
- GPR101 | c.346T>C p.F116L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV99981355; called by muse, mutect2, varscan2
- GPRC6A | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 25/148 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.783); catalogued as COSV100114240; called by muse, mutect2, varscan2
- GRIK2 | c.1507C>T p.R503C | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs1312199028, COSV59737564; called by muse, mutect2, varscan2
- GRIK4 | c.1167C>T p.I389= | Splice Region (SNP) | VAF 11/30 reads (37%) | catalogued as rs748528917, COSV101483581; called by muse, mutect2, varscan2
- GRIK4 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV70806445; called by muse, mutect2, varscan2
- GYS2 | c.1252G>A p.D418N | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs370887018; called by muse, mutect2, varscan2
- HDC | c.1041G>A p.M347I | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); catalogued as COSV99983942; called by muse, mutect2, varscan2
- HEATR6 | c.2858T>C p.I953T | Missense Mutation (SNP) | VAF 46/132 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs371496240, COSV99482242; called by muse, mutect2, varscan2
- HECW2 | c.2569G>A p.E857K | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99646685; called by muse, mutect2, varscan2
- HIPK2 | c.704C>T p.S235F | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100702141; called by muse, mutect2, varscan2
- HIRA | c.353T>A p.V118E | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.358); catalogued as COSV99600129; called by muse, mutect2, varscan2
- HNRNPDL | c.612+2T>G p.X204_splice | Splice Site (SNP) | VAF 40/149 reads (27%) | catalogued as COSV99787052; called by muse, mutect2, varscan2
- HPR | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 89/315 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV99930858; called by muse, mutect2, varscan2
- HRNR | c.944G>T p.G315V | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV100913274; called by muse, mutect2, varscan2
- HTR1B | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.71); PolyPhen benign (0.129); catalogued as rs780026953, COSV64051042; called by muse, mutect2, varscan2
- HYDIN | c.12154C>T p.H4052Y | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.046); catalogued as rs868484151, COSV101125006; called by muse, mutect2, varscan2
- IFNA10 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.102); catalogued as COSV99497433; called by muse, mutect2, varscan2
- IFT81 | c.1595A>T p.Y532F | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as COSV99655883; called by muse, mutect2
- IGSF10 | c.1226C>T p.P409L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56792447; called by muse, mutect2, varscan2
- IKZF3 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 37/123 reads (30%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV53105237; called by muse, mutect2, varscan2
- INPP4B | c.2222T>C p.V741A | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV99523875; called by muse, mutect2, varscan2
- IQGAP3 | c.2842G>A p.E948K | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV100752110; called by muse, mutect2, varscan2
- ITGA3 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50306875; called by muse, mutect2, varscan2
- ITIH4 | c.2578C>T p.L860F | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as COSV56573436; called by muse, mutect2, varscan2
- KCNQ3 | c.1544T>G p.L515R | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV101195885; called by muse, mutect2, varscan2
- KCNT2 | c.404T>A p.I135N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99652760; called by muse, mutect2
- KDM7A | c.2255G>A p.R752K | Missense Mutation (SNP) | VAF 96/192 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.015); catalogued as COSV99134206; called by muse, mutect2, varscan2
- KDM7A | c.2254A>G p.R752G | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99134210; called by muse, mutect2, varscan2
- KIF17 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as rs770015366, COSV56119544; called by muse, mutect2, varscan2
- KIF3B | c.539C>T p.S180F | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV65229719; called by muse, mutect2, varscan2
- KIFC1 | c.278C>T p.P93L | Missense Mutation (SNP) | VAF 57/220 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.356); catalogued as COSV100997093; called by muse, mutect2, varscan2
- KLHL24 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV99664836, COSV99665234; called by muse, mutect2, varscan2
- KLK11 | c.334G>A p.E112K (on ENST00000594768 / NM_144947.3; = p.E80K on NM_006853.3) | Missense Mutation (SNP) | VAF 63/168 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51578129; called by muse, mutect2, varscan2
- KLK3 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs182759459, COSV58098938; called by muse, mutect2, varscan2
- KMT2A | c.7474C>T p.L2492F | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); catalogued as COSV100628505, COSV100628893; called by muse, mutect2, varscan2
- LAMB1 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.175); catalogued as COSV99740415; called by muse, mutect2
- LCOR | c.1873C>T p.P625S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs756790371, COSV99616765; called by muse, mutect2, varscan2
- LELP1 | c.149A>G p.E50G | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100907338; called by muse, mutect2, varscan2
- LHX4 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV99761348; called by muse, mutect2, varscan2
- LIPG | c.1360G>A p.G454R | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99724393; called by muse, mutect2, varscan2
- LMF2 | c.2099C>T p.S700L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs561600584, COSV53316890, COSV99327426; called by muse, mutect2, varscan2
- LPAR4 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 60/110 reads (55%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV101425100; called by muse, mutect2, varscan2
- LPO | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747592185, COSV99228638; called by muse, mutect2, varscan2
- LRIG1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 72/158 reads (46%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99833513; called by muse, mutect2, varscan2
- LRP1B | c.10744G>A p.E3582K | Missense Mutation (SNP) | VAF 28/224 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV67266617; called by muse, varscan2
- LRRC31 | c.668C>T p.P223L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as COSV99246289, COSV99246560; called by muse, mutect2, varscan2
- LRRC74A | c.113G>A p.R38Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1308171872, COSV53613948; called by muse, mutect2, varscan2
- LRRN1 | c.1546G>A p.V516I | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV100076195; called by muse, mutect2, varscan2
- LRRTM4 | c.1664C>T p.P555L | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs1305773955, COSV101298524; called by muse, varscan2
- LVRN | c.2960G>T p.R987M | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV100773314; called by muse, mutect2, varscan2
- LY75 | c.2323A>G p.I775V | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV99716282; called by muse, mutect2, varscan2
- MAGEC3 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs775758163, COSV100025177; called by muse, varscan2
- MANBA | c.2461C>T p.L821F (on ENST00000642252; = p.L775F on NM_005908.4) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.278); catalogued as rs1200976546, COSV99898554; called by muse, mutect2, varscan2
- MARCHF10 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 38/169 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60885561, COSV60888677; called by muse, mutect2, varscan2
- MASP1 | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99397022; called by muse, mutect2, varscan2
- MCM8 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99177547; called by muse, mutect2, varscan2
- MGAM | c.2827G>A p.D943N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs747835199, COSV101527358; called by muse, mutect2, varscan2
- MICAL3 | c.3895C>T p.Q1299* | Nonsense Mutation (SNP) | VAF 26/203 reads (13%) | catalogued as COSV101490843; called by muse, mutect2, varscan2
- MICALL2 | c.322G>A p.G108S | Missense Mutation (SNP) | VAF 65/264 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs779199787, COSV52519478, COSV99875846; called by muse, mutect2, varscan2
- MIGA1 | c.1123A>T p.M375L | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100889760; called by muse, mutect2, varscan2
- MKRN1 | c.847A>G p.I283V | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.246); catalogued as rs990968415, COSV99751531; called by muse, mutect2
- MLF2 | c.454T>A p.S152T | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV99180069, COSV99180103; called by muse, mutect2, varscan2
- MME | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs551727774, COSV100852347; called by muse, mutect2, varscan2
- MOSPD3 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 83/198 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV56159243; called by muse, mutect2, varscan2
- MPP7 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 46/85 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100517221; called by muse, mutect2, varscan2
- MROH2B | c.2714G>A p.R905K | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1435843855, COSV101270624; called by muse, mutect2, varscan2
- MSLNL | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs781065439, COSV99558144; called by muse, mutect2, varscan2
- MTMR9 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV99644147; called by muse, mutect2, varscan2
- MUC16 | c.33104C>T p.S11035L | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.07); catalogued as rs1568739792, COSV67478941; called by muse, mutect2, varscan2
- MUC16 | c.7246C>T p.P2416S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as rs1471557355, COSV101199327; called by muse, mutect2, varscan2
- MUC16 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs773754733, COSV67443953; called by muse, mutect2, varscan2
- MUC4 | c.14570C>T p.P4857L (on ENST00000463781 / NM_018406.7; = p.P621L on NM_004532.6) | Missense Mutation (SNP) | VAF 63/229 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV100204260; called by muse, mutect2, varscan2
- MUC5B | c.9137G>T p.R3046M | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as COSV101500221, COSV71594353; called by muse, mutect2, varscan2
- MYCBPAP | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.719); catalogued as COSV100087970; called by muse, mutect2, varscan2
- MYH8 | c.4531G>A p.E1511K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV101238358; called by muse, mutect2, varscan2
- MYH8 | c.4336G>A p.D1446N | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as rs779629902, COSV67971949; called by muse, mutect2, varscan2
- MYOM1 | c.1409C>T p.S470F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99866100; called by muse, mutect2, varscan2
- MYOZ2 | c.202T>A p.Y68N | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100201617; called by muse, mutect2, varscan2
- NADK2 | c.409C>T p.R137C | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs539457956, COSV99237375; called by muse, mutect2, varscan2
- NARS1 | c.10+1G>A p.X4_splice | Splice Site (SNP) | VAF 25/111 reads (23%) | catalogued as COSV99900544; called by muse, mutect2, varscan2
- NCAM1 | c.1621C>T p.L541F (on ENST00000316851 / NM_181351.5; = p.L531F on NM_000615.7) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV100377397, COSV100378174; called by muse, mutect2
- NDUFAF3 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 97/249 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.802); catalogued as COSV100454996; called by muse, mutect2, varscan2
- NEK4 | c.2075A>T p.D692V | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99237461; called by muse, mutect2, varscan2
- NES | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 64/185 reads (35%) | catalogued as COSV100957828; called by muse, mutect2, varscan2
- NET1 | c.1442T>A p.L481Q (on ENST00000355029 / NM_001047160.3; = p.L427Q on NM_005863.5) | Missense Mutation (SNP) | VAF 86/215 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100742256; called by muse, mutect2, varscan2
- NFASC | c.3695C>T p.P1232L (on ENST00000339876 / NM_001378329.1; = p.P1161L on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100363417; called by muse, mutect2, varscan2
- NGEF | c.1259A>G p.K420R | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157845742, COSV99888762; called by muse, mutect2, varscan2
- NGEF | c.1258A>T p.K420* | Nonsense Mutation (SNP) | VAF 46/135 reads (34%) | catalogued as COSV99888764; called by muse, mutect2, varscan2
- NLRP11 | c.593G>A p.S198N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100789699; called by muse, mutect2, varscan2
- NMUR1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.206); catalogued as COSV100531899; called by muse, mutect2, varscan2
- NMUR2 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 18/107 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV54920339; called by muse, mutect2, varscan2
- NOMO1 | c.2707C>T p.R903C | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1357773385, COSV55057659, COSV99814442; called by muse, mutect2
- NOX3 | c.1322G>A p.W441* | Nonsense Mutation (SNP) | VAF 22/74 reads (30%) | catalogued as COSV50150148; called by muse, mutect2, varscan2
- NRXN1 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs906827517, COSV101279430, COSV68018753; called by muse, mutect2, varscan2
- NSMF | c.1256A>G p.Y419C (on ENST00000371475 / NM_001130969.3; = p.Y417C on NM_015537.4) | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1359133904, COSV99689154; called by muse, mutect2, varscan2
- OLFM4 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99524268; called by muse, mutect2, varscan2
- OR2AT4 | c.757G>A p.V253M | Missense Mutation (SNP) | VAF 41/81 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765037281, COSV100532320; called by muse, mutect2, varscan2
- OR2Z1 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV60691984, COSV60692689; called by muse, mutect2, varscan2
- OR4S2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100412610; called by muse, mutect2, varscan2
- OR51A4 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as COSV66749047; called by muse, mutect2, varscan2
- OR52B4 | c.608C>T p.S203F | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.042); catalogued as COSV68769216; called by muse, mutect2, varscan2
- OR5H1 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.102); catalogued as COSV100641623, COSV100641667; called by muse, mutect2, varscan2
- OR6C70 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/66 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.378); catalogued as COSV100524387, COSV59245434; called by muse, mutect2, varscan2
- OR6C75 | c.872G>A p.R291K | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.339); catalogued as COSV100595303; called by muse, mutect2, varscan2
- OR7A5 | c.754T>A p.Y252N | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs62122651, COSV100457691; called by muse, mutect2
- OR7A5 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV100457693, COSV100457812; called by muse, mutect2
- OR7G3 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV100555660; called by muse, mutect2, varscan2
- OR9Q1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV59036616; called by muse, mutect2, varscan2
- ORC4 | c.44A>T p.E15V | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV99932084; called by muse, mutect2, varscan2
- OSBP2 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV100212896; called by muse, mutect2, varscan2
- PATL1 | c.1031G>A p.R344K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.92); catalogued as rs1169730370, COSV100274848; called by muse, mutect2, varscan2
- PAX8 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV54507069, COSV54511215; called by muse, mutect2, varscan2
- PAX8 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV54507080; called by muse, mutect2, varscan2
- PBXIP1 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.08); catalogued as COSV100870060; called by muse, mutect2, varscan2
- PCDHAC1 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs946542782, COSV99165593; called by muse, mutect2, varscan2
- PCDHAC2 | c.2545G>A p.E849K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.014); catalogued as COSV53872506; called by muse, mutect2, varscan2
- PCDHB1 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60631644; called by muse, mutect2, varscan2
- PCDHB16 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.057); catalogued as COSV53358626; called by muse, mutect2, varscan2
- PCDHB8 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 48/490 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV50759980; called by muse, mutect2
- PCDHGA1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs201338329, COSV65298095; called by muse, mutect2, varscan2
- PCLO | c.13583G>A p.G4528E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs199732601; called by muse, mutect2, varscan2
- PCLO | c.10278G>T p.M3426I | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61626604; called by muse, mutect2, varscan2
- PCLO | c.5153C>T p.S1718L | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs374430015; called by muse, mutect2, varscan2
- PDPN | c.361G>A p.V121I (on ENST00000621990; = p.V197I on NM_006474.4) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as rs1284601082, COSV99611328; called by muse, mutect2, varscan2
- PDZRN4 | c.2713C>T p.P905S (on ENST00000402685 / NM_001164595.2; = p.P647S on NM_013377.4) | Missense Mutation (SNP) | VAF 25/231 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100114148; called by muse, mutect2, varscan2
- PGD | c.1436C>T p.S479L | Missense Mutation (SNP) | VAF 34/274 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.295); catalogued as rs749994897, COSV99581298; called by muse, mutect2, varscan2
- PHACTR3 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.129); catalogued as rs1462411157, COSV100732423; called by muse, mutect2, varscan2
- PIANP | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.995); catalogued as rs1187464752, COSV100272316; called by muse, mutect2, varscan2
- PIANP | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.996); catalogued as rs749295458, COSV100272317; called by muse, mutect2, varscan2
- PIK3R4 | c.54T>G p.S18R | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV100768336; called by muse, mutect2, varscan2
- PITPNM2 | c.1339G>A p.G447S | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT tolerated (0.63); PolyPhen benign (0.173); catalogued as rs142319238, COSV99758636; called by muse, mutect2, varscan2
- PKD1L1 | c.3361G>A p.G1121S | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.388); catalogued as COSV99219196; called by muse, mutect2, varscan2
- PLCE1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 48/119 reads (40%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV53351013; called by muse, mutect2, varscan2
- PLCH1 | c.2773C>T p.P925S (on ENST00000340059 / NM_001130960.2; = p.P917S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100396251; called by muse, mutect2, varscan2
- PLD3 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.026); catalogued as COSV100735149; called by muse, mutect2, varscan2
- PLG | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.379); catalogued as rs961449882, COSV99804519; called by muse, mutect2, varscan2
- PLTP | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 71/358 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs370451864; called by muse, mutect2, varscan2
- PNLDC1 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV51705277, COSV99277297; called by muse, mutect2, varscan2
- PNPLA8 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs762605000, COSV99993494; called by muse, mutect2, varscan2
- POLR3B | c.1310C>T p.T437I | Missense Mutation (SNP) | VAF 93/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99943282; called by muse, mutect2, varscan2
- POU2F2 | c.11C>T p.S4F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.272); catalogued as COSV100657312; called by muse, mutect2, varscan2
- PPARGC1A | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.253); catalogued as COSV99337703; called by muse, mutect2, varscan2
- PPFIA4 | c.972T>G p.N324K | Missense Mutation (SNP) | VAF 60/304 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99829800; called by muse, mutect2, varscan2
- PPP1R12B | c.1254+1G>A p.X418_splice | Splice Site (SNP) | VAF 15/80 reads (19%) | catalogued as COSV100406951; called by mutect2, varscan2
- PRKCQ | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54116188; called by muse, mutect2, varscan2
- PRKD1 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100120693, COSV59590385; called by muse, mutect2, varscan2
- PRKG2 | c.2161G>C p.A721P | Missense Mutation (SNP) | VAF 43/141 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV100019638; called by muse, mutect2, varscan2
- PRKG2 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100019642; called by muse, mutect2, varscan2
- PRLR | c.1048G>A p.G350S | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99184300; called by muse, mutect2, varscan2
- PROM2 | c.1375G>A p.D459N | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs144977181; called by muse, mutect2, varscan2
- PRPSAP2 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.072); catalogued as COSV52064929; called by muse, mutect2, varscan2
- PRRX1 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); catalogued as COSV99509514; called by muse, mutect2, varscan2
- PSD3 | c.2299C>T p.R767C (on ENST00000440756; = p.R766C on NM_015310.4) | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs149616744; called by muse, mutect2, varscan2
- PSMB11 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 99/216 reads (46%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1485667036, COSV101273393, COSV101273435; called by muse, mutect2, varscan2
- PSMB4 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 87/361 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV51850911; called by muse, mutect2
- PTCH1 | c.757C>T p.P253S | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.028); catalogued as COSV59465688, COSV59479444; called by muse, mutect2, varscan2
- PTK7 | c.2890C>T p.R964C | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs763046153, COSV57851453; called by muse, mutect2, varscan2
- PXDNL | c.2036G>A p.G679E | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs757085857, COSV100682932, COSV62490001; called by muse, mutect2, varscan2
- R3HDM1 | c.2848C>A p.P950T | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99926021; called by muse, mutect2, varscan2
- RAD51AP2 | c.2956G>A p.E986K | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.33); catalogued as COSV101208315; called by muse, mutect2, varscan2
- RALGPS2 | c.748A>C p.I250L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100243757; called by muse, mutect2, varscan2
- RASAL3 | c.2291G>A p.G764E | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV99652974; called by muse, mutect2
- RASSF9 | c.1030A>C p.K344Q | Missense Mutation (SNP) | VAF 45/358 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.836); catalogued as rs762148101, COSV100771305; called by muse, mutect2, varscan2
- RBM34 | c.137A>T p.E46V | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV100783936; called by muse, mutect2, varscan2
- REEP2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs756954484, COSV99649560; called by muse, mutect2, varscan2
- RETREG2 | c.511C>T p.H171Y | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.97); PolyPhen benign (0.011); catalogued as COSV99811482; called by muse, mutect2, varscan2
- RHAG | c.1166G>A p.G389E | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.498); catalogued as COSV100006487; called by muse, mutect2, varscan2
- RIMS3 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1431071442, COSV101013365; called by muse, mutect2, varscan2
- RIPOR1 | c.2425C>T p.R809C (on ENST00000379312 / NM_001193522.2; = p.R805C on NM_024519.4) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs748266857, COSV99242871; called by muse, mutect2, varscan2
- RIPOR3 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 20/257 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs555386385, COSV50396183; called by muse, mutect2
- RND1 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 83/255 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs1395870529, COSV59045891; called by muse, mutect2, varscan2
- RNF215 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.333); catalogued as COSV99306468; called by muse, mutect2, varscan2
- ROS1 | c.575G>A p.G192E | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100876873; called by muse, mutect2, varscan2
- RPAP2 | c.1455+1G>A p.X485_splice | Splice Site (SNP) | VAF 24/81 reads (30%) | catalogued as COSV101532170; called by muse, mutect2, varscan2
- RPL3L | c.1160C>T p.A387V | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.341); catalogued as COSV99238146; called by muse, mutect2, varscan2
- RRAD | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 36/127 reads (28%) | catalogued as COSV100233777; called by muse, mutect2, varscan2
- RTN4 | c.3553C>T p.P1185S (on ENST00000337526 / NM_020532.5; = p.P192S on NM_007008.3) | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100462968; called by muse, mutect2, varscan2
- RUFY4 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV60246066; called by muse, mutect2, varscan2
- RXFP2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV53636791; called by muse, mutect2, varscan2
- RYR3 | c.9112G>A p.G3038R (on ENST00000389232; = p.G3039R on NM_001036.6) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.4); PolyPhen benign (0.189); catalogued as COSV101212437; called by muse, mutect2, varscan2
- SAMD9 | c.1805C>T p.S602L | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV66075383; called by muse, mutect2, varscan2
- SCAF4 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99741251, COSV99741258; called by muse, mutect2, varscan2
- SCN7A | c.1981G>A p.D661N | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0.046); catalogued as COSV101313160; called by muse, mutect2, varscan2
- SDCCAG8 | c.1069-2A>T p.X357_splice | Splice Site (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100654087; called by muse, varscan2
- SECISBP2L | c.1841C>T p.P614L (on ENST00000559471 / NM_001193489.2; = p.P569L on NM_014701.4) | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99960136; called by muse, mutect2, varscan2
- SERPINB4 | c.172C>T p.H58Y | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as COSV100345600; called by muse, mutect2, varscan2
- SGMS1 | c.832G>A p.G278R | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100693273; called by muse, mutect2, varscan2
- SHH | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as CM991130, COSV99793361; called by muse, mutect2, varscan2
- SHQ1 | c.413C>T p.S138L | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV100344802; called by muse, mutect2, varscan2
- SIRPB1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV99498299; called by muse, mutect2, varscan2
- SLC12A5 | c.3112G>A p.A1038T (on ENST00000454036 / NM_001134771.2; = p.A1015T on NM_020708.5) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99275417; called by muse, mutect2, varscan2
- SLC15A2 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 54/208 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99815374; called by muse, mutect2, varscan2
- SLC1A1 | c.538A>T p.T180S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV99261259; called by muse, mutect2, varscan2
- SLC26A5 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.043); catalogued as rs753131965, COSV100099011, COSV59698449; called by muse, mutect2, varscan2
- SLC26A8 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1217288652, COSV100839423; called by muse, mutect2, varscan2
- SLC36A2 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100079044; called by muse, mutect2, varscan2
- SLC4A1 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV52258880, COSV99293214; called by muse, mutect2, varscan2
- SLC52A2 | c.1125+2T>G p.X375_splice | Splice Site (SNP) | VAF 27/176 reads (15%) | catalogued as COSV100095624; called by muse, mutect2, varscan2
- SLC6A5 | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV54229107, COSV54234143; called by muse, mutect2, varscan2
- SLC9C2 | c.2176A>T p.I726L | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.005); catalogued as rs377240801; called by muse, mutect2, varscan2
- SLIT2 | c.4532C>T p.S1511F | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs1182658447, COSV56589915; called by muse, mutect2, varscan2
- SLX4 | c.4754C>T p.P1585L | Missense Mutation (SNP) | VAF 56/212 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as COSV99567865; called by muse, mutect2, varscan2
- SMTN | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 64/189 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV100294213; called by muse, mutect2, varscan2
- SMYD1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.484); catalogued as COSV101352416; called by muse, mutect2, varscan2
- SNAI1 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 166/367 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs754163516, COSV99723880; called by muse, mutect2, varscan2
- SORBS1 | c.1913C>T p.A638V (on ENST00000361941 / NM_001034954.2; = p.A344V on NM_006434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as COSV99527758; called by muse, mutect2, varscan2
- SOWAHB | c.1583G>A p.R528Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs199835098, COSV100530664; called by muse, mutect2, varscan2
- SP100 | c.2195C>T p.S732F | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV60846763; called by muse, mutect2, varscan2
- SP140 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as COSV59455634; called by muse, mutect2, varscan2
- SPG21 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.057); catalogued as COSV99200183; called by muse, mutect2, varscan2
- SPHKAP | c.4625G>A p.R1542Q | Missense Mutation (SNP) | VAF 115/349 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs368367152, COSV60881066; called by muse, mutect2, varscan2
- SPPL2C | c.32G>A p.G11D | Missense Mutation (SNP) | VAF 60/149 reads (40%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.831); catalogued as rs1485389721, COSV100233999; called by muse, mutect2, varscan2
- SPR | c.638C>A p.S213Y | Missense Mutation (SNP) | VAF 28/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99318022; called by muse, mutect2, varscan2
- SPTBN1 | c.5186A>T p.D1729V | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100442265; called by muse, mutect2, varscan2
- ST7 | c.1420C>T p.P474S (on ENST00000265437 / NM_021908.3; = p.P451S on NM_018412.4) | Missense Mutation (SNP) | VAF 26/355 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55383583; called by muse, mutect2
- STAB1 | c.1981A>T p.I661F | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100401502; called by muse, mutect2, varscan2
- STK31 | c.1359A>C p.E453D | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100669282; called by muse, mutect2, varscan2
- STK36 | c.2300C>T p.S767F | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV55331869, COSV99831201; called by muse, mutect2, varscan2
- STK40 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs749663576, COSV100828560; called by muse, mutect2, varscan2
- STXBP1 | c.983C>T p.S328F | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100964547; called by muse, mutect2, varscan2
- SUCLG2 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100214107; called by muse, mutect2
- SULT2B1 | c.228G>A p.M76I (on ENST00000201586 / NM_177973.2; = p.M61I on NM_004605.2) | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.398); catalogued as rs1316371984, COSV99572167; called by muse, mutect2, varscan2
- SUPT5H | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.025); catalogued as rs1041370601, COSV63238826; called by muse, mutect2, varscan2
- SVEP1 | c.4371G>A p.M1457I | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV57033287; called by muse, mutect2, varscan2
- SYMPK | c.3773C>T p.P1258L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as rs769451270, COSV99679700; called by muse, mutect2, varscan2
- SYNE1 | c.17626C>T p.P5876S (on ENST00000367255 / NM_182961.4; = p.P5805S on NM_033071.3) | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); catalogued as COSV55138082; called by muse, mutect2, varscan2
- SYNE2 | c.3800C>T p.S1267F | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100647326; called by muse, mutect2, varscan2
- SYNPO2 | c.1849C>T p.P617S | Missense Mutation (SNP) | VAF 56/201 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100205314; called by muse, mutect2, varscan2
- SYTL3 | c.1348G>A p.E450K (on ENST00000611299 / NM_001242394.1; = p.E382K on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV99791783; called by muse, mutect2, varscan2
- TAOK2 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV99664297; called by muse, varscan2
- TARS2 | c.10T>G p.Y4D | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV100945922; called by muse, mutect2, varscan2
- TBX4 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99540080; called by muse, mutect2, varscan2
- TCHHL1 | c.1792G>A p.G598R | Missense Mutation (SNP) | VAF 93/294 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1251298629, COSV64286890; called by muse, mutect2, varscan2
- TENM3 | c.5650G>A p.D1884N | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs200581858, COSV69314507; called by muse, mutect2, varscan2
- TESMIN | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV99663568; called by muse, mutect2, varscan2
- TIAM2 | c.404G>A p.G135E | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as COSV100018546; called by muse, mutect2, varscan2
- TLCD5 | c.674C>T p.A225V (on ENST00000375095 / NM_001198671.2; = p.A128V on NM_174926.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as COSV100080994; called by muse, mutect2, varscan2
- TLR2 | c.2107C>T p.L703F | Missense Mutation (SNP) | VAF 75/196 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472236; called by muse, mutect2, varscan2
- TMEM108 | c.1115C>T p.S372F | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV100418622; called by muse, mutect2, varscan2
- TMEM222 | c.599C>T p.T200I | Missense Mutation (SNP) | VAF 42/187 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV100929953; called by muse, mutect2, varscan2
- TNFAIP2 | c.1946C>T p.S649F | Missense Mutation (SNP) | VAF 114/266 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60694545; called by muse, mutect2, varscan2
- TNIP3 | c.653G>A p.R218Q | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1277441435, COSV50249730; called by muse, mutect2, varscan2
- TNNI3 | c.550-1G>A p.X184_splice | Splice Site (SNP) | VAF 6/84 reads (7%) | catalogued as rs1555863017, COSV52572508; ClinVar: uncertain significance; called by muse, mutect2
- TNRC18 | c.5413C>T p.R1805* | Nonsense Mutation (SNP) | VAF 7/54 reads (13%) | catalogued as COSV101269622; called by muse, mutect2, varscan2
- TNS2 | c.4061G>A p.R1354K (on ENST00000314250 / NM_170754.4; = p.R1364K on NM_015319.2) | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV100036644; called by muse, mutect2, varscan2
- TPRN | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1323380430; called by muse, mutect2
- TPTE | c.1502C>T p.S501F (on ENST00000618007 / NM_199261.4; = p.S483F on NM_199259.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as rs1411624452; called by muse, mutect2, varscan2
- TPTE | c.1522C>T p.L508F (on ENST00000618007 / NM_199261.4; = p.L490F on NM_199259.4) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs1432945554; called by muse, mutect2
- TRH | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.437); catalogued as rs772388530, COSV57014858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM55 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV52543884; called by muse, mutect2, varscan2
- TRMT1 | c.1688C>T p.P563L | Missense Mutation (SNP) | VAF 45/219 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53400804; called by muse, mutect2, varscan2
- TRPM5 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99329941; called by mutect2, varscan2
- TRPM6 | c.3952G>A p.E1318K | Missense Mutation (SNP) | VAF 112/410 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as rs1212446742, COSV100666109; called by muse, mutect2, varscan2
- TRPV4 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.071); catalogued as COSV99924570; called by muse, mutect2, varscan2
- TTBK1 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs753761636, COSV52489471; called by muse, mutect2, varscan2
- TTN | c.66458G>A p.G22153E (on ENST00000591111; = p.G14729E on NM_003319.4) | Missense Mutation (SNP) | VAF 44/144 reads (31%) | PolyPhen benign (0.204); catalogued as COSV100604409; called by muse, mutect2, varscan2
- TTN | c.58835G>A p.G19612E (on ENST00000591111; = p.G12188E on NM_003319.4) | Missense Mutation (SNP) | VAF 9/35 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV100620309, COSV60260095; called by muse, mutect2, varscan2
- TTN | c.29131C>T p.L9711F (on ENST00000591111; = p.L8784F on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/176 reads (31%) | PolyPhen benign (0.04); catalogued as COSV100604417; called by muse, mutect2, varscan2
- TUBAL3 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV100990512; called by muse, mutect2, varscan2
- TYRP1 | c.524A>T p.N175I | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.453); catalogued as COSV101141261; called by muse, mutect2, varscan2
- UBXN10 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 31/94 reads (33%) | catalogued as COSV100907762; called by muse, mutect2, varscan2
- UCK2 | c.281T>A p.I94N | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100902913; called by muse, mutect2, varscan2
- USF2 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 62/354 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99723087; called by muse, mutect2, varscan2
- USP34 | c.776C>T p.P259L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.981); catalogued as COSV101276891; called by muse, mutect2, varscan2
- VCAM1 | c.1826C>A p.P609H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99658391; called by muse, mutect2, varscan2
- VCAN | c.5353G>A p.E1785K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.072); catalogued as COSV99424300, COSV99425333; called by muse, mutect2, varscan2
- VNN2 | c.1291C>T p.L431F | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100426745, COSV100426774; called by muse, mutect2, varscan2
- VNN3 | c.570T>A p.D190E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as COSV99258187; called by muse, mutect2, varscan2
- VWF | c.7083C>T p.A2361= | Splice Region (SNP) | VAF 24/69 reads (35%) | catalogued as rs557817663, COSV99778654; called by muse, mutect2, varscan2
- XIRP2 | c.7231G>A p.E2411K (on ENST00000628543; = p.E2586K on NM_152381.6) | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV54687370, COSV54715184; called by muse, mutect2, varscan2
- XKR3 | c.440G>A p.R147K | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100509203, COSV58887539; called by muse, mutect2, varscan2
- ZBTB20 | c.2134G>A p.G712R (on ENST00000474710 / NM_001164342.2; = p.G639R on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as rs771234012, COSV100613400; called by muse, mutect2, varscan2
- ZFX | c.1987A>T p.K663* | Nonsense Mutation (SNP) | VAF 37/87 reads (43%) | catalogued as COSV100457473; called by muse, mutect2, varscan2
- ZHX2 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100072842; called by muse, mutect2, varscan2
- ZKSCAN3 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99356866; called by muse, mutect2, varscan2
- ZMIZ2 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.937); catalogued as COSV99536756; called by muse, mutect2, varscan2
- ZMPSTE24 | c.590T>A p.F197Y | Missense Mutation (SNP) | VAF 51/405 reads (13%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV101031925; called by muse, mutect2, varscan2
- ZNF112 | c.2227C>T p.H743Y (on ENST00000337401 / NM_001083335.2; = p.H737Y on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 67/346 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100495631; called by muse, mutect2, varscan2
- ZNF211 | c.1550C>T p.S517F (on ENST00000347302 / NM_198855.4; = p.S530F on NM_006385.5) | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.275); catalogued as rs199579625, COSV53741599; called by muse, mutect2, varscan2
- ZNF273 | c.1690C>T p.H564Y | Missense Mutation (SNP) | VAF 37/133 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as COSV100139241; called by muse, mutect2, varscan2
- ZNF28 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 84/476 reads (18%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV100354405; called by muse, mutect2, varscan2
- ZNF43 | c.1406T>C p.L469P | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100731770; called by muse, mutect2, varscan2
- ZNF502 | c.1364G>A p.R455K | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV99939636; called by muse, mutect2, varscan2
- ZNF528 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100846636; called by muse, mutect2, varscan2
- ZNF595 | c.1504C>T p.H502Y | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100227560; called by muse, mutect2, varscan2
- ZNF597 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV100071953; called by muse, mutect2, varscan2
- ZNF613 | c.1588C>T p.H530Y (on ENST00000293471 / NM_001031721.4; = p.H494Y on NM_024840.4) | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99522886; called by muse, mutect2, varscan2
- ZNF711 | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0.05); PolyPhen benign (0.378); catalogued as COSV99340886; called by muse, mutect2, varscan2
- ZNF804A | c.2851C>T p.P951S | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.852); catalogued as COSV56435462; called by muse, mutect2, varscan2
- ZNRF3 | c.1322C>T p.S441F (on ENST00000544604 / NM_001206998.2; = p.S341F on NM_032173.3) | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs776552725, COSV100238232; called by muse, mutect2, varscan2
- ZP1 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV53927883; called by muse, mutect2
- ZP2 | c.1036C>T p.R346W | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.224); catalogued as rs531980914, COSV99559355; called by muse, mutect2, varscan2
- ZSCAN26 | c.1191C>A p.N397K (on ENST00000623276 / NM_001111039.2; = p.N263K on NM_152736.5) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.572); catalogued as rs754428219, COSV52554727; called by muse, mutect2, varscan2
- ZSCAN5B | c.913T>A p.S305T | Missense Mutation (SNP) | VAF 76/262 reads (29%) | SIFT tolerated (0.85); PolyPhen benign (0.253); catalogued as COSV100627926; called by muse, mutect2
- AP2B1 | c.2095G>A p.G699R | Missense Mutation (SNP) | VAF 64/188 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- CFAP221 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 32/204 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGHA1 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.58); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRC1 | c.1175G>A p.R392K | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); called by muse, mutect2
- MRPL45 | c.439del p.E147Kfs*6 | Frame Shift Del (DEL) | VAF 38/138 reads (28%) | called by mutect2, varscan2
- SLIT3 | c.1310A>T p.N437I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPATA5 | c.457_479del p.M153Dfs*49 | Frame Shift Del (DEL) | VAF 15/64 reads (23%) | called by mutect2, pindel, varscan2
- TRAV10 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- TRBV2 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRBV20-1 | c.151C>T p.R51C | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- TYK2 | c.1575_1577delinsTG p.R527Gfs*12 | Frame Shift Del (DEL) | VAF 13/64 reads (20%) | called by pindel, varscan2*
- UBE2NL | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 53/104 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ZMYM2 | c.3738_3751delinsA p.H1246Qfs*3 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | called by pindel, varscan2*
- ACE2 | c.1074C>T p.I358= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as COSV53025062; called by muse, mutect2, varscan2
- ADAMTS10 | c.942C>T p.F314= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as COSV54360583, COSV99547518; called by muse, mutect2, varscan2
- ADCY5 | c.3048C>T p.F1016= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV59202391; called by muse, mutect2
- ADCY8 | c.675G>A p.V225= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs527430954, COSV53901370; called by muse, mutect2, varscan2
- ADGRV1 | c.6330C>T p.I2110= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV101315727; called by muse, mutect2, varscan2
- AHNAK2 | c.8754C>T p.V2918= | Silent (SNP) | VAF 224/464 reads (48%) | catalogued as rs375802197; called by muse, mutect2, varscan2
- AK8 | c.708C>T p.I236= | Silent (SNP) | VAF 92/303 reads (30%) | catalogued as COSV53754222; called by muse, mutect2, varscan2
- AKR1B10 | c.99G>A p.K33= | Silent (SNP) | VAF 40/219 reads (18%) | catalogued as COSV62056015; called by muse, mutect2, varscan2
- AKR1D1 | c.744G>A p.G248= | Silent (SNP) | VAF 94/221 reads (43%) | catalogued as COSV54340878; called by muse, mutect2, varscan2
- ALDH16A1 | c.1485C>T p.S495= | Silent (SNP) | VAF 125/383 reads (33%) | catalogued as rs755256724, COSV99512773; called by muse, mutect2, varscan2
- ALPP | c.990C>T p.L330= | Silent (SNP) | VAF 38/146 reads (26%) | catalogued as rs773342740, COSV101235125; called by muse, mutect2, varscan2
- APOB | c.11190C>T p.F3730= | Silent (SNP) | VAF 37/261 reads (14%) | catalogued as rs75165693, COSV51924522; called by muse, mutect2, varscan2
- ARHGAP31 | c.3777G>A p.K1259= | Silent (SNP) | VAF 26/69 reads (38%) | catalogued as COSV99956888; called by muse, mutect2, varscan2
- ARID1A | c.1557C>T p.S519= | Silent (SNP) | VAF 213/702 reads (30%) | catalogued as COSV100251072; called by muse, mutect2, varscan2
- ARID1A | c.2562T>G p.P854= | Silent (SNP) | VAF 22/177 reads (12%) | catalogued as COSV100251074; called by muse, mutect2, varscan2
- ATP6V0A4 | c.411C>T p.F137= | Silent (SNP) | VAF 206/413 reads (50%) | catalogued as COSV100022975; called by muse, mutect2, varscan2
- AXIN1 | c.2562C>T p.I854= | Silent (SNP) | VAF 84/282 reads (30%) | catalogued as COSV99249605; called by muse, mutect2, varscan2
- AXL | c.453C>T p.A151= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs767629887, COSV99996303; called by mutect2, varscan2
- B3GNT5 | c.240G>A p.K80= | Silent (SNP) | VAF 40/167 reads (24%) | catalogued as COSV100191997; called by muse, mutect2, varscan2
- BCL2L12 | c.51C>T p.F17= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as rs267605591, COSV55862539; called by muse, mutect2, varscan2
- BRINP2 | c.1338C>T p.P446= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100837979; called by muse, mutect2, varscan2
- BTNL3 | c.666G>A p.L222= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as rs563357818, COSV61565680; called by muse, mutect2, varscan2
- C15orf39 | c.1008C>T p.P336= | Silent (SNP) | VAF 59/189 reads (31%) | catalogued as COSV100641277; called by muse, mutect2, varscan2
- C17orf98 | c.99G>A p.R33= | Silent (SNP) | VAF 37/142 reads (26%) | called by muse, mutect2, varscan2
- CABS1 | c.408C>T p.S136= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV99909022, COSV99909126; called by muse, mutect2, varscan2
- CACNA1S | c.1824C>T p.F608= | Silent (SNP) | VAF 31/159 reads (19%) | catalogued as COSV100754874; called by muse, mutect2, varscan2
- CASZ1 | c.1563C>T p.S521= | Silent (SNP) | VAF 34/108 reads (31%) | catalogued as rs1444947620, COSV100681117; called by muse, mutect2, varscan2
- CCDC127 | c.516C>T p.I172= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs1305827284, COSV99722942; called by muse, mutect2, varscan2
- CCDC69 | c.246G>A p.R82= | Silent (SNP) | VAF 37/187 reads (20%) | catalogued as COSV100815140; called by muse, mutect2, varscan2
- CCDC7 | c.3870C>T p.I1290= | Silent (SNP) | VAF 33/101 reads (33%) | catalogued as COSV100177997; called by muse, mutect2, varscan2
- CD163 | c.3462G>A p.G1154= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as COSV100775785; called by muse, mutect2, varscan2
- CD163 | c.147G>A p.K49= | Silent (SNP) | VAF 47/164 reads (29%) | catalogued as COSV100775786; called by muse, mutect2, varscan2
- CD1E | c.861G>A p.V287= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV100936961; called by muse, mutect2
- CDH10 | c.276C>T p.I92= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as COSV100050903; called by muse, mutect2
- CDHR3 | c.2037C>T p.V679= | Silent (SNP) | VAF 50/405 reads (12%) | catalogued as COSV58414527; called by muse, mutect2, varscan2
- CFAP221 | c.2058C>T p.P686= | Silent (SNP) | VAF 31/202 reads (15%) | catalogued as COSV99732242; called by muse, mutect2, varscan2
- CMTM8 | c.459C>T p.T153= | Silent (SNP) | VAF 48/103 reads (47%) | catalogued as COSV100282470; called by muse, mutect2, varscan2
- COG7 | c.1398G>A p.Q466= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as COSV100207490; called by muse, mutect2, varscan2
- COL12A1 | c.5472C>T p.S1824= | Silent (SNP) | VAF 33/104 reads (32%) | catalogued as COSV100485736; called by muse, mutect2, varscan2
- COL4A2 | c.2859A>G p.G953= | Silent (SNP) | VAF 60/138 reads (43%) | catalogued as COSV100847300; called by muse, mutect2
- COL5A3 | c.2619G>A p.L873= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- COL6A3 | c.735C>T p.F245= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as rs1156348094, COSV99797343; called by muse, mutect2, varscan2
- CSMD2 | c.1749C>T p.T583= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as COSV99588429; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1761T>C p.P587= | Silent (SNP) | VAF 39/158 reads (25%) | catalogued as COSV99599892; called by muse, mutect2, varscan2
- CX3CR1 | c.366C>T p.V122= | Silent (SNP) | VAF 94/172 reads (55%) | catalogued as COSV100843166; called by muse, mutect2, varscan2
- CYP11B2 | c.483G>T p.V161= | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as COSV100010908; called by muse, mutect2, varscan2
- CYTH2 | c.798C>T p.L266= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV57311301; called by muse, mutect2, varscan2
- DCAF5 | c.1227C>T p.V409= | Silent (SNP) | VAF 38/200 reads (19%) | catalogued as COSV58464066; called by muse, mutect2, varscan2
- DCC | c.894C>T p.S298= | Silent (SNP) | VAF 51/178 reads (29%) | catalogued as COSV100499152; called by muse, mutect2, varscan2
- DCC | c.2925G>A p.G975= | Silent (SNP) | VAF 78/235 reads (33%) | catalogued as rs267605209, COSV59086305; called by muse, mutect2, varscan2
- DENND3 | c.57C>T p.L19= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs1368450908, COSV99370726; called by muse, mutect2, varscan2
- DISP3 | c.1554G>A p.L518= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV53825278, COSV99608129; called by muse, mutect2, varscan2
- DNAH10 | c.12408C>T p.I4136= (on ENST00000409039; = p.I4075= on NM_207437.3) | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV68992161; called by muse, mutect2, varscan2
- DNAH17 | c.5001C>T p.T1667= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs770041344, COSV101101933; called by muse, mutect2, varscan2
- DNAH3 | c.8799A>T p.V2933= | Silent (SNP) | VAF 156/508 reads (31%) | catalogued as COSV99766321; called by muse, mutect2, varscan2
- DNAH5 | c.12324C>T p.F4108= | Silent (SNP) | VAF 19/74 reads (26%) | catalogued as COSV54201346; called by muse, mutect2, varscan2
- DNAH8 | c.3705G>A p.Q1235= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV100544286; called by muse, mutect2, varscan2
- DNM2 | c.243C>T p.A81= | Silent (SNP) | VAF 34/162 reads (21%) | catalogued as rs755366581, COSV100117069; called by muse, mutect2, varscan2
- DOK7 | c.1269G>A p.Q423= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as rs1247286969, COSV100403283; called by muse, mutect2, varscan2
- DSG3 | c.1215C>T p.I405= | Silent (SNP) | VAF 38/142 reads (27%) | catalogued as COSV99934009; called by muse, mutect2, varscan2
- DZIP3 | c.861C>T p.F287= | Silent (SNP) | VAF 43/148 reads (29%) | catalogued as COSV100847734; called by muse, mutect2, varscan2
- ENTPD8 | c.696C>T p.L232= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV100395502; called by muse, mutect2, varscan2
- EPHA6 | c.3392G>A p.*1131= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV101061738; called by mutect2, varscan2
- EPHB3 | c.1416C>T p.S472= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV100382955; called by muse, mutect2, varscan2
- EXOC4 | c.856T>C p.L286= | Silent (SNP) | VAF 28/182 reads (15%) | catalogued as COSV99553240; called by muse, mutect2, varscan2
- FAM110C | c.735C>T p.T245= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as rs1332800169, COSV100566837; called by muse, mutect2, varscan2
- FAM135B | c.1095G>A p.Q365= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs748954204, COSV52716884, COSV99421960; called by muse, mutect2, varscan2
- FAM47A | c.2049G>A p.S683= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV60496127; called by muse, mutect2, varscan2
- FAT4 | c.10923G>A p.Q3641= | Silent (SNP) | VAF 48/169 reads (28%) | catalogued as COSV100628095; called by muse, mutect2, varscan2
- FBH1 | c.963C>T p.L321= (on ENST00000362091 / NM_178150.3; = p.L372= on NM_032807.4) | Silent (SNP) | VAF 45/107 reads (42%) | catalogued as COSV100758684; called by muse, mutect2, varscan2
- FLVCR1 | c.426C>T p.T142= | Silent (SNP) | VAF 22/151 reads (15%) | catalogued as COSV100757898; called by muse, mutect2, varscan2
- FNDC1 | c.1479G>A p.V493= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99795431; called by muse, mutect2, varscan2
- FRAS1 | c.774C>T p.P258= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV99350369; called by muse, mutect2, varscan2
- FZD8 | c.1518C>T p.S506= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV101020206; called by muse, mutect2, varscan2
- GCG | c.249G>A p.R83= | Silent (SNP) | VAF 56/299 reads (19%) | catalogued as COSV64960866, COSV64961946; called by muse, mutect2, varscan2
- GGT7 | c.861C>T p.R287= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV100321859; called by muse, mutect2, varscan2
- GIMAP1 | c.894G>A p.E298= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as rs1374692819, COSV56187645; called by muse, mutect2, varscan2
- GIMAP6 | c.651G>A p.E217= | Silent (SNP) | VAF 212/490 reads (43%) | catalogued as rs1389952175, COSV61033638; called by muse, mutect2, varscan2
- GIMAP6 | c.180C>T p.I60= | Silent (SNP) | VAF 189/869 reads (22%) | catalogued as COSV100188178; called by muse, mutect2, varscan2
- GLI2 | c.2251C>T p.L751= (on ENST00000361492 / NM_001374353.1; = p.L768= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs200831069; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- GORAB | c.808T>C p.L270= | Silent (SNP) | VAF 14/91 reads (15%) | catalogued as rs1267193568, COSV100883822; called by muse, mutect2, varscan2
- GRIK4 | c.1614C>T p.S538= | Silent (SNP) | VAF 24/169 reads (14%) | catalogued as COSV70804241; called by muse, mutect2, varscan2
- GUCY1A1 | c.30G>A p.K10= | Silent (SNP) | VAF 38/86 reads (44%) | catalogued as COSV99637532; called by muse, mutect2, varscan2
- HDAC9 | c.3135G>A p.V1045= (on ENST00000441542 / NM_178425.3; = p.V1042= on NM_178423.3) | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV101286649; called by muse, mutect2, varscan2
- HDC | c.1608G>A p.R536= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV99983941; called by muse, mutect2, varscan2
- HEXB | c.1515G>A p.R505= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV99714204; called by muse, mutect2
- HEYL | c.588G>A p.L196= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs753832825, COSV100865283; called by muse, mutect2, varscan2
- HIVEP1 | c.159C>T p.I53= | Silent (SNP) | VAF 81/283 reads (29%) | catalogued as rs267600783, COSV65105193; called by muse, mutect2, varscan2
- HNF4A | c.768G>A p.P256= | Silent (SNP) | VAF 59/208 reads (28%) | catalogued as rs760173369, COSV57386783; called by muse, mutect2, varscan2
- HS3ST1 | c.531C>T p.F177= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as COSV50027946; called by muse, mutect2, varscan2
- HUS1B | c.225C>T p.L75= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV100033336; called by muse, mutect2, varscan2
- IGF2R | c.2595C>T p.L865= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV63626609; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.22C>T p.L8= | Silent (SNP) | VAF 73/247 reads (30%) | catalogued as rs762289704; called by muse, mutect2, varscan2
- IL17RA | c.1093C>T p.L365= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs1340192314, COSV100083020; called by muse, varscan2
- ILDR1 | c.1611C>T p.S537= (on ENST00000344209 / NM_001199799.2; = p.S493= on NM_175924.4) | Silent (SNP) | VAF 29/114 reads (25%) | catalogued as COSV99878167; called by muse, mutect2, varscan2
- INTS2 | c.2043T>C p.S681= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV99247978; called by muse, mutect2, varscan2
- IQCG | c.267A>G p.R89= | Silent (SNP) | VAF 38/169 reads (22%) | catalogued as rs745865584, COSV99502235; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.198C>T p.P66= | Silent (SNP) | VAF 40/179 reads (22%) | catalogued as COSV101188262; called by muse, mutect2, varscan2
- ITGB7 | c.1900C>T p.L634= | Silent (SNP) | VAF 49/138 reads (36%) | catalogued as COSV99914021; called by muse, mutect2, varscan2
- KCNA5 | c.1713G>A p.E571= | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as rs147455567; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNH6 | c.2742C>T p.S914= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV100120932; called by muse, mutect2
- KEL | c.984C>T p.S328= | Silent (SNP) | VAF 95/384 reads (25%) | catalogued as rs200342923, COSV100786996; called by muse, mutect2, varscan2
- KIAA0408 | c.540C>T p.S180= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as COSV64107809; called by muse, mutect2, varscan2
- KIAA1958 | c.1509C>T p.F503= | Silent (SNP) | VAF 33/77 reads (43%) | catalogued as COSV100515981; called by muse, mutect2, varscan2
- KIF1B | c.3660C>T p.F1220= (on ENST00000377086 / NM_001365952.1; = p.F1174= on NM_015074.3) | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV99822988; called by muse, mutect2
- KSR2 | c.396G>A p.E132= | Silent (SNP) | VAF 30/151 reads (20%) | catalogued as COSV100348168; called by muse, mutect2, varscan2
- LAMA5 | c.10884C>T p.T3628= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as rs778719671, COSV53377662; called by muse, mutect2, varscan2
- LMOD1 | c.393G>A p.K131= | Silent (SNP) | VAF 88/267 reads (33%) | catalogued as COSV100939123, COSV104426537; called by muse, mutect2, varscan2
- LRRC8A | c.1107G>A p.K369= | Silent (SNP) | VAF 62/139 reads (45%) | catalogued as COSV99396443; called by muse, mutect2, varscan2
- MAD1L1 | c.2070C>T p.I690= | Silent (SNP) | VAF 95/209 reads (45%) | catalogued as rs753443371, COSV56249958; called by muse, mutect2, varscan2
- MAP1A | c.2142G>A p.E714= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV100288419; called by muse, mutect2, varscan2
- MAP3K5 | c.3474C>T p.I1158= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100752667; called by muse, mutect2, varscan2
- MCHR2 | c.606G>A p.T202= | Silent (SNP) | VAF 27/107 reads (25%) | catalogued as rs267600746; called by muse, mutect2, varscan2
- MEIS1 | c.525C>T p.S175= | Silent (SNP) | VAF 79/328 reads (24%) | catalogued as COSV99714928; called by muse, mutect2, varscan2
- MGRN1 | c.1267C>T p.L423= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as COSV99273987; called by muse, mutect2, varscan2
- MKI67 | c.6603C>T p.F2201= | Silent (SNP) | VAF 118/312 reads (38%) | catalogued as COSV100896392; called by muse, varscan2
- MKNK1 | c.117C>T p.T39= | Silent (SNP) | VAF 24/90 reads (27%) | catalogued as COSV100361164; called by muse, mutect2, varscan2
- MORC1 | c.759C>T p.F253= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as rs1418281464, COSV99225671; called by muse, mutect2, varscan2
- MRGPRX1 | c.822C>T p.F274= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as rs866353263, COSV57105708; called by muse, mutect2, varscan2
- MS4A10 | c.438C>T p.L146= | Silent (SNP) | VAF 59/136 reads (43%) | catalogued as COSV100382265, COSV100382465; called by muse, mutect2, varscan2
- MUC16 | c.23610C>T p.S7870= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as rs756082634, COSV67440966; called by muse, mutect2, varscan2
- MUC16 | c.21747G>A p.R7249= | Silent (SNP) | VAF 35/182 reads (19%) | catalogued as rs1217933050, COSV101199326; called by muse, mutect2, varscan2
- MUC21 | c.1590T>A p.P530= | Silent (SNP) | VAF 33/121 reads (27%) | catalogued as COSV100888850; called by muse, mutect2, varscan2
- MYH1 | c.5457G>A p.L1819= | Silent (SNP) | VAF 56/188 reads (30%) | catalogued as COSV99875494; called by muse, mutect2, varscan2
- NDN | c.249G>A p.P83= | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as COSV100086271, COSV59358953; called by muse, mutect2
- NDUFAF3 | c.309C>T p.S103= | Silent (SNP) | VAF 99/252 reads (39%) | catalogued as COSV100454995; called by muse, mutect2, varscan2
- NEFM | c.2604T>G p.G868= | Silent (SNP) | VAF 47/120 reads (39%) | catalogued as COSV99647143; called by muse, mutect2, varscan2
- NEUROD6 | c.483C>T p.F161= | Silent (SNP) | VAF 39/151 reads (26%) | catalogued as rs1397560367, COSV51769478; called by muse, mutect2, varscan2
- NFASC | c.3099C>T p.F1033= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs1286438344, COSV100363415; called by muse, mutect2, varscan2
- NLRP11 | c.819C>T p.F273= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as COSV100789698; called by muse, mutect2, varscan2
- NLRP3 | c.1227C>T p.I409= | Silent (SNP) | VAF 37/132 reads (28%) | catalogued as COSV60224842; called by muse, mutect2, varscan2
- NMUR1 | c.180C>T p.F60= | Silent (SNP) | VAF 11/97 reads (11%) | catalogued as COSV59405980; called by muse, mutect2, varscan2
- NOG | c.360C>T p.I120= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100240547; called by muse, mutect2, varscan2
- NOMO2 | c.633C>T p.P211= | Silent (SNP) | VAF 21/189 reads (11%) | catalogued as COSV100395627; called by muse, mutect2, varscan2
- NOTCH4 | c.1233C>T p.P411= | Silent (SNP) | VAF 40/137 reads (29%) | catalogued as rs765479460, COSV100900592; called by muse, mutect2, varscan2
- NTN4 | c.1290T>A p.R430= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as COSV100643737; called by muse, mutect2, varscan2
- OR10Q1 | c.786C>T p.L262= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as rs371940725; called by muse, mutect2, varscan2
- OR11L1 | c.519G>A p.Q173= | Silent (SNP) | VAF 61/202 reads (30%) | catalogued as COSV63314882, COSV63316277; called by muse, varscan2
- OR13C4 | c.183C>T p.F61= | Silent (SNP) | VAF 43/171 reads (25%) | catalogued as COSV52927438; called by muse, mutect2, varscan2
- PADI4 | c.1845G>A p.K615= | Silent (SNP) | VAF 28/73 reads (38%) | catalogued as rs368571418, COSV100966747; called by muse, mutect2, varscan2
- PBXIP1 | c.1116G>A p.R372= | Silent (SNP) | VAF 40/189 reads (21%) | catalogued as rs150382643; called by muse, mutect2, varscan2
- PCDHA1 | c.2226C>T p.S742= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs782810577, COSV100974332; called by muse, mutect2, varscan2
- PCDHA12 | c.2241T>C p.S747= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99165592; called by muse, mutect2, varscan2
- PDE1C | c.381C>T p.F127= | Silent (SNP) | VAF 44/176 reads (25%) | catalogued as COSV100370673, COSV100372003; called by muse, mutect2, varscan2
- PDE9A | c.435C>T p.I145= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV52330610; called by muse, mutect2, varscan2
- PHF21B | c.696C>T p.I232= | Silent (SNP) | VAF 62/209 reads (30%) | catalogued as COSV100503672; called by muse, mutect2, varscan2
- PHF21B | c.246C>T p.L82= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as rs1429434839, COSV57558065; called by muse, mutect2, varscan2
- PLOD1 | c.2160C>T p.I720= | Silent (SNP) | VAF 47/173 reads (27%) | catalogued as rs140513387; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PLXNB3 | c.2934C>T p.I978= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs139989610, COSV100737285; called by muse, mutect2, varscan2
- PNMT | c.753G>A p.R251= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV99510539; called by muse, mutect2, varscan2
- POM121 | c.2091C>T p.S697= (on ENST00000434423; = p.S432= on NM_172020.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/133 reads (20%) | catalogued as COSV99988000; called by muse, mutect2, varscan2
- POTEF | c.96C>T p.F32= | Silent (SNP) | VAF 152/438 reads (35%) | catalogued as COSV100664750; called by muse, mutect2, varscan2
- PPARGC1B | c.915C>T p.P305= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as rs750530995, COSV100494629; called by muse, mutect2, varscan2
- PRAMEF2 | c.720C>T p.S240= | Silent (SNP) | VAF 57/253 reads (23%) | catalogued as COSV99535073; called by muse, mutect2, varscan2
- PRDM15 | c.423C>T p.F141= | Silent (SNP) | VAF 35/147 reads (24%) | catalogued as rs112850683, COSV54148707; called by muse, mutect2, varscan2
- PRDM9 | c.2232G>A p.G744= | Silent (SNP) | VAF 45/265 reads (17%) | catalogued as COSV99690217; called by muse, varscan2
- PSD | c.1599G>A p.L533= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs779567626, COSV99192384; called by muse, mutect2, varscan2
- PSMB4 | c.90C>T p.S30= | Silent (SNP) | VAF 90/366 reads (25%) | catalogued as COSV99304943; called by muse, mutect2
- PUS10 | c.783C>T p.F261= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100369482; called by muse, mutect2, varscan2
- PWWP3B | c.1506G>A p.R502= | Silent (SNP) | VAF 19/37 reads (51%) | catalogued as COSV100531102; called by muse, mutect2, varscan2
- PYHIN1 | c.1290C>T p.T430= | Silent (SNP) | VAF 56/173 reads (32%) | catalogued as COSV100932342, COSV63724647; called by muse, mutect2, varscan2
- RABL6 | c.1812C>T p.G604= | Silent (SNP) | VAF 51/146 reads (35%) | catalogued as COSV100273169; called by muse, mutect2, varscan2
- RAX | c.423G>T p.T141= | Silent (SNP) | VAF 84/273 reads (31%) | catalogued as COSV56875618; called by muse, mutect2, varscan2
- RHAG | c.990C>T p.V330= | Silent (SNP) | VAF 25/178 reads (14%) | catalogued as COSV100006488; called by muse, mutect2, varscan2
- RHBDL3 | c.408C>T p.I136= | Silent (SNP) | VAF 39/107 reads (36%) | catalogued as rs1248721322, COSV99283629; called by muse, mutect2, varscan2
- RIMS1 | c.612A>T p.V204= | Silent (SNP) | VAF 41/147 reads (28%) | catalogued as rs767598016, COSV99325675; called by muse, mutect2, varscan2
- RNF17 | c.1707C>T p.I569= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as rs1186273216, COSV99692782; called by muse, mutect2, varscan2
- RNF20 | c.657G>A p.Q219= | Silent (SNP) | VAF 30/117 reads (26%) | catalogued as COSV100874310; called by muse, mutect2, varscan2
- RNF215 | c.627C>T p.S209= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as COSV99306466; called by muse, mutect2, varscan2
- RYR3 | c.2328C>T p.F776= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV101212436; called by muse, mutect2, varscan2
- SALL3 | c.1965G>A p.S655= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as rs369156685, COSV101609970; called by muse, mutect2, varscan2
- SBK1 | c.549C>T p.F183= | Silent (SNP) | VAF 9/38 reads (24%) | catalogued as COSV100543384; called by muse, mutect2, varscan2
- SCD5 | c.666G>A p.L222= | Silent (SNP) | VAF 39/111 reads (35%) | catalogued as COSV100124496; called by muse, mutect2, varscan2
- SCNM1 | c.429T>A p.L143= | Silent (SNP) | VAF 92/935 reads (10%) | catalogued as COSV99765961; called by muse, mutect2
- SEC14L4 | c.729G>A p.G243= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99742856; called by muse, mutect2, varscan2
- SEMA3G | c.357C>T p.F119= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs777943668, COSV99201920; called by muse, mutect2, varscan2
- SENP6 | c.2793C>T p.V931= | Silent (SNP) | VAF 20/89 reads (22%) | catalogued as rs370016028, COSV64186354; called by muse, mutect2, varscan2
- SENP7 | c.246C>T p.I82= | Silent (SNP) | VAF 108/389 reads (28%) | catalogued as COSV100052866; called by muse, mutect2, varscan2
- SERPINA10 | c.645G>A p.G215= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs367966236; called by muse, mutect2, varscan2
- SERPINA11 | c.663C>T p.F221= | Silent (SNP) | VAF 80/189 reads (42%) | catalogued as COSV100593998; called by muse, mutect2, varscan2
- SHPK | c.1425G>A p.Q475= | Silent (SNP) | VAF 76/223 reads (34%) | catalogued as COSV99843802; called by muse, mutect2, varscan2
- SLC24A4 | c.912C>T p.P304= | Silent (SNP) | VAF 35/73 reads (48%) | catalogued as rs374332198; called by muse, mutect2, varscan2
- SLC44A5 | c.750G>A p.T250= | Silent (SNP) | VAF 50/135 reads (37%) | catalogued as rs201160398, COSV63763820; called by muse, mutect2, varscan2
- SLC49A3 | c.546C>T p.S182= | Silent (SNP) | VAF 31/117 reads (26%) | catalogued as COSV100448426; called by muse, mutect2, varscan2
- SLC7A10 | c.570C>T p.F190= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV99472150; called by muse, mutect2, varscan2
- SLC9A4 | c.2355G>A p.R785= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV54841160; called by muse, mutect2, varscan2
- SLCO6A1 | c.1135C>T p.L379= | Silent (SNP) | VAF 12/66 reads (18%) | catalogued as rs1007372367, COSV65806197, COSV65813347; called by muse, mutect2, varscan2
- SORCS2 | c.1200C>T p.F400= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs764275522, COSV61167510; called by muse, mutect2, varscan2
- SORCS3 | c.1839C>T p.F613= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as rs766009113, COSV63830669; called by muse, varscan2
- SOX7 | c.1053C>T p.L351= | Silent (SNP) | VAF 30/76 reads (39%) | catalogued as COSV100449020; called by muse, mutect2, varscan2
- SP100 | c.2196C>T p.S732= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as rs181313295; called by muse, mutect2, varscan2
- SRRM4 | c.1404C>T p.P468= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV99938233; called by muse, mutect2, varscan2
- STAB2 | c.5115C>T p.I1705= | Silent (SNP) | VAF 46/231 reads (20%) | catalogued as COSV101185821, COSV66341076; called by muse, mutect2, varscan2
- STIM1 | c.660C>T p.I220= | Silent (SNP) | VAF 49/120 reads (41%) | catalogued as rs200982503, COSV56153169; called by muse, mutect2, varscan2
- STK40 | c.360C>T p.I120= | Silent (SNP) | VAF 121/389 reads (31%) | catalogued as rs745965678, COSV63734615; called by muse, mutect2, varscan2
- SYT10 | c.873T>G p.T291= | Silent (SNP) | VAF 21/89 reads (24%) | catalogued as COSV57346683, COSV99951189; called by muse, mutect2, varscan2
- TBX4 | c.594C>T p.I198= | Silent (SNP) | VAF 85/266 reads (32%) | catalogued as rs147048921; called by muse, mutect2, varscan2
- TCEA2 | c.582C>T p.S194= | Silent (SNP) | VAF 40/198 reads (20%) | catalogued as rs1208882786, COSV100180666; called by muse, mutect2, varscan2
- TFAP2D | c.108C>T p.S36= | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as COSV99145833; called by muse, mutect2, varscan2
- TIAM2 | c.904C>T p.L302= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV100018550; called by muse, mutect2, varscan2
- TMED9 | c.576C>T p.F192= | Silent (SNP) | VAF 24/113 reads (21%) | catalogued as rs773114554, COSV99218916; called by muse, mutect2, varscan2
- TMEM132D | c.2991C>T p.F997= | Silent (SNP) | VAF 48/184 reads (26%) | catalogued as rs368677574; called by muse, mutect2, varscan2
- TMEM178A | c.849G>A p.R283= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as rs970061523, COSV99931841; called by muse, mutect2, varscan2
- TMEM222 | c.600C>T p.T200= | Silent (SNP) | VAF 41/184 reads (22%) | catalogued as rs200116563, COSV65026947; called by muse, mutect2, varscan2
- TMIGD1 | c.390C>T p.F130= | Silent (SNP) | VAF 23/186 reads (12%) | catalogued as COSV100187196; called by muse, mutect2, varscan2
- TRBV29-1 | c.24C>T p.L8= | Silent (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- TRBV29-1 | c.261C>T p.N87= | Silent (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- TRIM55 | c.312C>T p.I104= | Silent (SNP) | VAF 60/151 reads (40%) | catalogued as COSV52548946, COSV52550488; called by muse, mutect2, varscan2
- TRPC7 | c.1056C>T p.F352= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV61457855; called by muse, mutect2, varscan2
- TST | c.333G>A p.R111= | Silent (SNP) | VAF 38/108 reads (35%) | catalogued as COSV99968173; called by muse, mutect2, varscan2
- TTC9 | c.600G>A p.V200= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as rs1285151521, COSV99832798; called by muse, mutect2, varscan2
- TTLL2 | c.450C>T p.T150= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99514575; called by muse, mutect2, varscan2
- TYRP1 | c.408A>G p.L136= | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as COSV66358610; called by muse, mutect2, varscan2
- UBE4B | c.3312C>T p.V1104= (on ENST00000343090 / NM_001105562.3; = p.V975= on NM_006048.5) | Silent (SNP) | VAF 27/71 reads (38%) | catalogued as COSV99476222; called by muse, mutect2, varscan2
- UGGT2 | c.1557C>T p.F519= | Silent (SNP) | VAF 52/138 reads (38%) | catalogued as COSV100948583; called by muse, mutect2, varscan2
- UGT2B4 | c.1488C>T p.F496= | Silent (SNP) | VAF 99/312 reads (32%) | catalogued as COSV59318224; called by muse, mutect2, varscan2
- UNC13C | c.2994T>A p.S998= | Silent (SNP) | VAF 31/145 reads (21%) | catalogued as COSV99514873, COSV99520221; called by muse, mutect2, varscan2
- UPF1 | c.45C>T p.F15= | Silent (SNP) | VAF 8/99 reads (8%) | catalogued as COSV99439219; called by muse, mutect2
- UTP4 | c.744A>G p.E248= | Silent (SNP) | VAF 87/302 reads (29%) | catalogued as COSV100076899; called by muse, mutect2, varscan2
- VAMP7 | c.609C>T p.I203= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV52901402; called by muse, mutect2, varscan2
- VAPA | c.261G>T p.P87= | Silent (SNP) | VAF 63/201 reads (31%) | catalogued as COSV100486074, COSV61297182; called by muse, mutect2, varscan2
- VSTM4 | c.396C>T p.I132= | Silent (SNP) | VAF 51/121 reads (42%) | catalogued as COSV100039254; called by muse, mutect2, varscan2
- WNT7B | c.498C>T p.F166= | Silent (SNP) | VAF 45/160 reads (28%) | catalogued as rs1406170408, COSV100254872; called by muse, mutect2, varscan2
- WWC1 | c.1068C>T p.F356= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs770982007, COSV99514005; called by muse, mutect2, varscan2
- XIRP1 | c.5073C>T p.N1691= | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as COSV100453516; called by muse, mutect2, varscan2
- XYLT2 | c.2469T>A p.A823= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV99190841; called by muse, mutect2
- ZCCHC13 | c.21C>T p.F7= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as COSV59866069; called by muse, mutect2, varscan2
- ZNF165 | c.300C>T p.I100= | Silent (SNP) | VAF 22/105 reads (21%) | catalogued as COSV101055884; called by muse, mutect2, varscan2
- ZNF230 | c.1155C>T p.V385= | Silent (SNP) | VAF 55/159 reads (35%) | catalogued as COSV101431964; called by muse, mutect2, varscan2
- ZNF300 | c.417G>A p.E139= | Silent (SNP) | VAF 28/164 reads (17%) | catalogued as COSV99199842; called by muse, mutect2, varscan2
- ZNF384 | c.825C>T p.I275= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV100158369; called by muse, mutect2, varscan2
- ZNF404 | c.726C>T p.P242= | Silent (SNP) | VAF 52/144 reads (36%) | catalogued as rs374757295; called by muse, mutect2, varscan2
- ZNF462 | c.6678C>T p.S2226= | Silent (SNP) | VAF 40/142 reads (28%) | catalogued as COSV99471368; called by muse, mutect2, varscan2
- ZNF470 | c.274C>T p.L92= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as COSV100401182; called by muse, mutect2
- ZNF583 | c.879G>A p.E293= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs1303940081, COSV99382052; called by muse, mutect2, varscan2
- ZNF649 | c.219C>T p.I73= | Silent (SNP) | VAF 27/154 reads (18%) | catalogued as COSV100725394; called by muse, mutect2, varscan2
- ZSCAN5B | c.915C>T p.S305= | Silent (SNP) | VAF 74/258 reads (29%) | catalogued as COSV100627924; called by muse, mutect2
- ZZEF1 | c.3375C>T p.F1125= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as rs761505456, COSV67557007; called by muse, mutect2, varscan2
- ATP6AP1L | n.1726G>A | RNA (SNP) | VAF 15/78 reads (19%) | catalogued as rs770479126, COSV101205117; called by muse, mutect2, varscan2
- FGFR3 | c.*794G>C | 3'UTR (SNP) | VAF 33/297 reads (11%) | catalogued as rs761196249, COSV53426590, COSV99601353; called by muse, mutect2, varscan2
- HERC2P3 | n.422C>T | RNA (SNP) | VAF 12/107 reads (11%) | called by muse, mutect2, varscan2
- MEF2C | c.402+179C>T | Intron (SNP) | VAF 11/65 reads (17%) | catalogued as COSV100425098; called by muse, mutect2, varscan2
- MIR376B | n.71G>A | RNA (SNP) | VAF 13/26 reads (50%) | called by muse, mutect2, varscan2
- MKNK2 | c.*1799C>T | 3'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs534046508, COSV99170248; called by mutect2, varscan2
- MOCS2 | c.-124C>T | 5'UTR (SNP) | VAF 10/58 reads (17%) | catalogued as COSV63741408; called by muse, mutect2, varscan2
- PCDHGA5 | c.2421+16C>T | Intron (SNP) | VAF 40/159 reads (25%) | catalogued as rs1286412324; called by muse, mutect2, varscan2
- PKD1L2 | n.563C>T | RNA (SNP) | VAF 14/68 reads (21%) | called by muse, mutect2
- RORB-AS1 | n.886+261C>T | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as COSV65335058; called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-47965G>A | Intron (SNP) | VAF 34/110 reads (31%) | catalogued as COSV101043463; called by muse, mutect2, varscan2
- SNORD116-2 | n.70C>T | RNA (SNP) | VAF 93/344 reads (27%) | catalogued as rs779848940; called by muse, mutect2, varscan2
- SSPOP | n.13692G>A | RNA (SNP) | VAF 19/151 reads (13%) | catalogued as COSV100947231; called by muse, mutect2, varscan2
- TPK1 | c.613+17372C>T | Intron (SNP) | VAF 4/13 reads (31%) | catalogued as rs565641100, COSV100765574; called by muse, mutect2, varscan2
- TTN | c.10361-4982C>T | Intron (SNP) | VAF 40/197 reads (20%) | catalogued as COSV100604419; called by muse, mutect2, varscan2
